Somatic mutation profile of tumor specimen TARGET-20-PASWIM-09A (aliquot TARGET-20-PASWIM-09A-01D) from TARGET case TARGET-20-PASWIM, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.6 years (2,402 days).
Specimen TARGET-20-PASWIM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93d92e12-ada6-4fb5-b681-f22e05ea90cc.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASWIM-14A (Bone Marrow Normal), aliquot TARGET-20-PASWIM-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/604c3843-9909-4939-9b54-d428297acc61

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 93/194 reads (48%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 26/58 reads (45%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 106/266 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
